Somatic mutation profile of tumor specimen TARGET-20-PASDVA-09A (aliquot TARGET-20-PASDVA-09A-02D) from TARGET case TARGET-20-PASDVA, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,150 days).
Specimen TARGET-20-PASDVA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a2264bb-1f22-4379-b604-ff4d0295b5e6.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASDVA-14A (Bone Marrow Normal), aliquot TARGET-20-PASDVA-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94394b47-922f-44be-9e67-7bf0aaa439cc

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 101/370 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- P2RY2 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 109/296 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs751543491, COSV60778038; called by muse, mutect2
- SPEG | c.*753G>A | 3'UTR (SNP) | VAF 29/299 reads (10%) | catalogued as rs997582919; called by muse, mutect2
